Somatic mutation profile of tumor specimen TCGA-63-A5MI-01A (aliquot TCGA-63-A5MI-01A-12D-A27K-08) from TCGA case TCGA-63-A5MI, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA.
Specimen TCGA-63-A5MI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4d4cfcfa-fe23-4da9-9936-263a24b46a86.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-63-A5MI-10A (Blood Derived Normal), aliquot TCGA-63-A5MI-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/728ddbe0-622e-4652-aba0-afdcf847b205

The open-access MAF lists 216 somatic variants for this specimen: 163 protein-altering or splice-affecting, 49 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 136, Silent 49, Nonsense Mutation 13, Splice Site 4, Frame Shift Del 3, In Frame Del 3, Frame Shift Ins 2, Intron 2, Splice Region 1, 5'Flank 1, In Frame Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 34/57 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913483, CM950470, COSV53390026; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB8 | c.1310G>A p.R437Q (on ENST00000297504 / NM_001282291.2; = p.R420Q on NM_007188.5) | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as rs772895911, COSV52510901; called by muse, mutect2, varscan2
- ADARB2 | c.1810G>A p.E604K | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.297); catalogued as COSV101184580; called by muse, mutect2, varscan2
- ADGRA2 | c.4003G>A p.E1335K | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779798627, COSV99605174; called by muse, mutect2
- ADTRP | c.119G>A p.G40D | Missense Mutation (SNP) | VAF 42/202 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as COSV99995580; called by muse, mutect2, varscan2
- ANKRD46 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs376278571; called by muse, mutect2, varscan2
- ARFGEF3 | c.6476G>A p.R2159H | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs111914596; called by muse, mutect2, varscan2
- ARHGAP20 | c.265G>C p.D89H | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.102); catalogued as COSV99505670; called by muse, mutect2, varscan2
- ARL5B | c.226T>G p.S76A | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.039); catalogued as rs745953146, COSV101040418; called by muse, mutect2, varscan2
- ASTN1 | c.1104C>A p.S368R | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV99923397; called by muse, mutect2, varscan2
- ATG9A | c.381G>C p.Q127H | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.276); catalogued as COSV100037299; called by muse, mutect2, varscan2
- AVPR1A | c.612G>C p.W204C | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100146927; called by muse, mutect2, varscan2
- CA1 | c.491C>A p.A164D | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as COSV99810382; called by muse, mutect2, varscan2
- CACNA1G | c.408G>A p.M136I | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV100662713; called by muse, mutect2
- CAMTA1 | c.2248C>A p.P750T | Missense Mutation (SNP) | VAF 47/215 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.054); catalogued as COSV100352721; called by muse, mutect2, varscan2
- CEP57 | c.532G>C p.D178H | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as COSV100334855; called by muse, mutect2, varscan2
- CFAP47 | c.5291G>T p.R1764L | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100545770; called by muse, mutect2, varscan2
- CFAP91 | c.712G>A p.V238M | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.741); catalogued as COSV56338845, COSV99847583; called by muse, mutect2, varscan2
- CFLAR | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 56/419 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs955193277, COSV100010005; called by muse, mutect2, varscan2
- CHRDL2 | c.967C>A p.H323N | Missense Mutation (SNP) | VAF 49/147 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV99734171; called by muse, mutect2, varscan2
- CLEC4E | c.125G>A p.C42Y | Missense Mutation (SNP) | VAF 52/444 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100222779; called by muse, mutect2, varscan2
- CORO2A | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV100674175; called by muse, mutect2, varscan2
- COX6A1 | c.322G>C p.D108H | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV99984945; called by muse, mutect2, varscan2
- CPNE4 | c.239C>G p.T80S | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.013); catalogued as COSV101456842; called by muse, mutect2
- CUBN | c.10753T>C p.Y3585H | Missense Mutation (SNP) | VAF 54/92 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100913711; called by muse, mutect2, varscan2
- CYP11B1 | c.992C>G p.A331G | Missense Mutation (SNP) | VAF 142/330 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs1326688256, CM960468, COSV52830433, COSV99455840; called by muse, mutect2, varscan2
- CYP11B1 | c.92T>A p.V31D | Missense Mutation (SNP) | VAF 21/165 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as COSV99455842; called by muse, mutect2, varscan2
- CYP7A1 | c.1415G>T p.G472V | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.199); catalogued as COSV100052676; called by muse, mutect2, varscan2
- DAAM1 | c.1897G>A p.D633N | Missense Mutation (SNP) | VAF 60/247 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100658733; called by muse, mutect2, varscan2
- DCUN1D4 | c.644A>G p.N215S | Missense Mutation (SNP) | VAF 57/93 reads (61%) | SIFT tolerated (0.07); PolyPhen benign (0.105); catalogued as COSV100584766; called by muse, mutect2, varscan2
- DDX23 | c.565G>C p.E189Q | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.278); catalogued as COSV100340014; called by muse, mutect2, varscan2
- DIP2A | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.035); catalogued as rs1276967667, COSV100596450; called by muse, mutect2
- DLC1 | c.2038C>A p.H680N (on ENST00000276297 / NM_001348081.2; = p.H243N on NM_006094.5) | Missense Mutation (SNP) | VAF 51/109 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.119); catalogued as COSV99366104; called by muse, mutect2, varscan2
- DUSP22 | c.531C>A p.F177L | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV60529620; called by muse, mutect2, varscan2
- ERRFI1 | c.35G>C p.R12T | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.721); catalogued as COSV101088351; called by muse, mutect2, varscan2
- ESR2 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 39/281 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.354); catalogued as COSV50831678, COSV99964019; called by muse, mutect2, varscan2
- EVI5 | c.1024G>C p.D342H | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64829609; called by muse, mutect2, varscan2
- FAM111A | c.334C>T p.Q112* | Nonsense Mutation (SNP) | VAF 11/112 reads (10%) | catalogued as COSV100659499; called by muse, mutect2
- FBXO4 | c.1070G>A p.W357* | Nonsense Mutation (SNP) | VAF 16/113 reads (14%) | catalogued as COSV99715350; called by muse, mutect2, varscan2
- GAL3ST1 | c.445G>T p.V149L | Missense Mutation (SNP) | VAF 45/258 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.295); catalogued as rs1302143274, COSV100143279; called by muse, mutect2, varscan2
- GPR158 | c.278A>C p.Q93P | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.162); catalogued as COSV100894412; called by muse, mutect2
- GRIN2B | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101663219; called by muse, mutect2, varscan2
- GRM8 | c.1123G>C p.G375R | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.102); catalogued as COSV100286723; called by muse, mutect2, varscan2
- H2AC1 | c.11G>T p.R4L | Missense Mutation (SNP) | VAF 62/190 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.013); catalogued as COSV51237093, COSV99219604; called by muse, mutect2, varscan2
- HADHA | c.275C>T p.S92L | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101024261; called by muse, mutect2, varscan2
- HECW1 | c.3496G>A p.D1166N | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.721); catalogued as COSV101224397; called by muse, mutect2, varscan2
- HSD17B4 | c.2276C>G p.A759G (on ENST00000414835 / NM_001199291.3; = p.A734G on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); catalogued as COSV99820259; called by muse, mutect2, varscan2
- IFIH1 | c.650G>A p.G217D | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.08); catalogued as COSV99718958; called by muse, mutect2, varscan2
- IGHV3-30 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 36/464 reads (8%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.061); catalogued as rs778939031; called by muse, mutect2
- IL4R | c.1024T>C p.C342R | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV50164165; called by muse, mutect2
- ITGAX | c.343G>T p.E115* | Nonsense Mutation (SNP) | VAF 9/16 reads (56%) | catalogued as COSV99191552; called by muse, mutect2, varscan2
- ITSN1 | c.1784C>A p.S595* | Nonsense Mutation (SNP) | VAF 13/94 reads (14%) | catalogued as COSV101180639; called by muse, mutect2, varscan2
- KIF13A | c.4430A>G p.H1477R | Missense Mutation (SNP) | VAF 107/343 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs747611407, COSV99438704; called by muse, mutect2, varscan2
- KIF2C | c.1088C>G p.S363C | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV100945903; called by muse, mutect2, varscan2
- KIFAP3 | c.1646C>T p.P549L | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV63035513; called by muse, mutect2, varscan2
- KIT | c.2453A>G p.K818R | Missense Mutation (SNP) | VAF 70/136 reads (51%) | SIFT tolerated (0.73); PolyPhen benign (0.024); catalogued as COSV55403212; called by muse, mutect2, varscan2
- KRT76 | c.329G>A p.R110K | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.011); catalogued as COSV100196576; called by muse, mutect2, varscan2
- KRT76 | c.39G>T p.R13S | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV100196578; called by muse, mutect2, varscan2
- KRTAP6-1 | c.166C>A p.L56I | Missense Mutation (SNP) | VAF 64/181 reads (35%) | PolyPhen benign (0.071); catalogued as COSV100228857; called by muse, mutect2, varscan2
- LEF1 | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99490119; called by muse, mutect2
- LGALS3 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs755491373, COSV54306621; called by muse, mutect2, varscan2
- LIMK2 | c.1689C>G p.F563L | Missense Mutation (SNP) | VAF 24/265 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100059180; called by muse, mutect2
- LPA | c.4986G>A p.M1662I | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.221); catalogued as COSV100308292; called by muse, mutect2, varscan2
- LRP1B | c.2243G>T p.G748V | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.368); catalogued as COSV101262115, COSV67182187; called by muse, mutect2, varscan2
- LRRC4C | c.44G>A p.G15D | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated, low confidence (0.35); PolyPhen probably damaging (0.992); catalogued as COSV99540137; called by muse, mutect2, varscan2
- LRRTM4 | c.707T>G p.L236* | Nonsense Mutation (SNP) | VAF 6/35 reads (17%) | catalogued as COSV101297758; called by muse, mutect2, varscan2
- LTBP1 | c.5044A>G p.I1682V (on ENST00000404816 / NM_206943.4; = p.I1356V on NM_000627.4) | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.961); catalogued as rs1328923101, COSV99698980; called by muse, mutect2, varscan2
- MASP1 | c.893-2A>G p.X298_splice | Splice Site (SNP) | VAF 12/147 reads (8%) | catalogued as rs1487873347, COSV99397783; called by muse, mutect2
- MCHR2 | c.279G>A p.W93* | Nonsense Mutation (SNP) | VAF 20/109 reads (18%) | catalogued as COSV99912830; called by muse, mutect2, varscan2
- MLH1 | c.1795G>T p.E599* | Nonsense Mutation (SNP) | VAF 13/79 reads (16%) | catalogued as COSV99212850; called by muse, mutect2, varscan2
- MRTFA | c.2456C>G p.S819C | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as COSV100844445; called by muse, mutect2
- MUC16 | c.41560G>T p.E13854* | Nonsense Mutation (SNP) | VAF 22/102 reads (22%) | catalogued as COSV101110121; called by muse, mutect2, varscan2
- MYO9B | c.2128G>A p.E710K | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.854); catalogued as rs572825412, COSV68277634; called by muse, mutect2, varscan2
- NCBP1 | c.268G>C p.V90L | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.773); catalogued as COSV100912708; called by muse, mutect2, varscan2
- NDUFS6 | c.329G>T p.G110V | Missense Mutation (SNP) | VAF 101/185 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1436792715, COSV99929182; called by muse, mutect2, varscan2
- NEIL3 | c.1168C>G p.L390V | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV99221005; called by muse, mutect2, varscan2
- NFKBIE | c.1340G>A p.R447Q (on ENST00000275015; = p.R308Q on NM_004556.3) | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs745840298, COSV99241497; called by muse, mutect2, varscan2
- NIBAN3 | c.733G>C p.A245P | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56311197, COSV99962815; called by muse, mutect2, varscan2
- NME8 | c.1256C>G p.A419G | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99553977; called by muse, mutect2, varscan2
- NMU | c.242T>C p.L81P | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV51700034; called by muse, mutect2, varscan2
- NOS1 | c.319C>A p.L107M | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100501566; called by muse, mutect2
- NUTM1 | c.2740C>A p.L914I | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as COSV59218746; called by muse, mutect2, varscan2
- NXN | c.347A>G p.E116G | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.093); catalogued as COSV100403611; called by muse, varscan2
- OR13C8 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 32/203 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs773921698, COSV58611789, COSV58612274; called by muse, mutect2, varscan2
- OR4C6 | c.880A>T p.S294C | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.447); catalogued as COSV100051907, COSV58604586; called by muse, mutect2, varscan2
- OR52E2 | c.422A>G p.K141R | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.51); PolyPhen benign (0.02); catalogued as COSV100384964; called by muse, varscan2
- OR52N1 | c.529C>A p.P177T | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as rs761355183, COSV100398749; called by muse, mutect2, varscan2
- P2RY10 | c.265C>T p.L89F | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.215); catalogued as COSV50684910, COSV99409460; called by muse, mutect2, varscan2
- PABPC4 | c.1615C>G p.L539V | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs1338995379, COSV100790942; called by muse, mutect2, varscan2
- PCDH17 | c.2177T>A p.I726N | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100932161; called by muse, mutect2, varscan2
- PCDHGA7 | c.2107G>A p.V703I | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.034); catalogued as rs762264055, COSV53911330, COSV53992900; called by muse, mutect2, varscan2
- PCOLCE2 | c.677G>C p.R226T | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV55997514; called by muse, mutect2, varscan2
- PDE3A | c.1847-1G>C p.X616_splice | Splice Site (SNP) | VAF 21/59 reads (36%) | catalogued as COSV100762937, COSV62980609; called by muse, mutect2, varscan2
- PFKFB3 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 23/169 reads (14%) | PolyPhen benign (0.034); catalogued as rs140784797; called by muse, mutect2, varscan2
- PLB1 | c.488A>T p.D163V | Missense Mutation (SNP) | VAF 60/208 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372683206; called by muse, mutect2, varscan2
- PRCP | c.286A>T p.I96F | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100476578; called by muse, mutect2, varscan2
- PRDM8 | c.197G>A p.R66K | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV60202641; called by muse, mutect2, varscan2
- PXDN | c.1486G>C p.D496H | Missense Mutation (SNP) | VAF 51/159 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs746298361, COSV53231974, COSV53244949, COSV99415316; called by muse, mutect2, varscan2
- PYGL | c.90G>C p.K30N | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV99369201; called by muse, mutect2, varscan2
- RAB23 | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 11/73 reads (15%) | catalogued as rs762512079, COSV58097871; called by muse, mutect2, varscan2
- RALB | c.155G>C p.R52T | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99732894; called by muse, varscan2
- RALB | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV55602556; called by muse, varscan2
- RALY | c.700G>A p.G234S (on ENST00000246194 / NM_016732.3; = p.G218S on NM_007367.4) | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.36); catalogued as rs772759103, COSV99866288; called by muse, varscan2
- RASAL2 | c.716A>G p.K239R | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.65); PolyPhen benign (0.405); catalogued as rs1451943548, COSV100862982; called by muse, mutect2, varscan2
- RNF213 | c.571C>G p.Q191E | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.09); catalogued as COSV100174071; called by muse, mutect2
- RNF213 | c.667C>G p.P223A | Missense Mutation (SNP) | VAF 24/226 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs370235044; called by muse, varscan2
- RNF213 | c.1020G>C p.K340N | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.638); catalogued as COSV100174080; called by muse, varscan2
- RNF31 | c.1378G>A p.G460R | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV53760879, COSV99396346; called by muse, mutect2, varscan2
- RNF40 | c.904G>C p.E302Q | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100222396; called by muse, mutect2, varscan2
- ROBO4 | c.1799A>T p.Q600L | Missense Mutation (SNP) | VAF 54/81 reads (67%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV100127907; called by muse, mutect2, varscan2
- RYR3 | c.11888C>A p.S3963* (on ENST00000389232; = p.S3964* on NM_001036.6) | Nonsense Mutation (SNP) | VAF 36/156 reads (23%) | catalogued as COSV101215039, COSV66782274; called by muse, mutect2, varscan2
- SENP2 | c.625C>T p.Q209* | Nonsense Mutation (SNP) | VAF 12/106 reads (11%) | catalogued as COSV99958348; called by muse, mutect2, varscan2
- SIRPD | c.544C>A p.P182T | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.878); catalogued as COSV67546996; called by muse, mutect2, varscan2
- SLC25A40 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100353848; called by muse, mutect2, varscan2
- SLC35F4 | c.1187C>A p.A396D (on ENST00000339762 / NM_001352015.2; = p.A360D on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV100334336; called by muse, mutect2, varscan2
- SLC8A1 | c.1810A>G p.K604E | Missense Mutation (SNP) | VAF 47/157 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV100247643; called by muse, mutect2, varscan2
- SMARCD2 | c.1205_1207del p.K402del | In Frame Del (DEL) | VAF 24/151 reads (16%) | catalogued as rs748931861; called by pindel, varscan2
- SON | c.5459C>G p.S1820C | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV51658638, COSV99280219; called by muse, mutect2, varscan2
- SPTA1 | c.2668A>G p.R890G | Missense Mutation (SNP) | VAF 37/182 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.05); catalogued as COSV100935734; called by muse, mutect2, varscan2
- SREK1IP1 | c.25G>A p.D9N | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV101536201; called by muse, mutect2, varscan2
- STK36 | c.3884G>A p.R1295K | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT tolerated (0.07); PolyPhen benign (0.073); catalogued as COSV99832034; called by muse, mutect2, varscan2
- SULT1E1 | c.380T>C p.L127P | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99895302; called by muse, mutect2, varscan2
- SVEP1 | c.5260G>C p.D1754H | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99930035; called by muse, mutect2, varscan2
- SVIL | c.2759C>G p.S920C (on ENST00000355867 / NM_021738.3; = p.S494C on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.014); catalogued as rs770589221, COSV100881619; called by muse, mutect2, varscan2
- SYNE3 | c.257G>T p.R86L | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.198); catalogued as COSV100516652; called by muse, mutect2, varscan2
- TBC1D32 | c.1351A>G p.I451V | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.99); PolyPhen benign (0.01); catalogued as rs372997464; called by muse, mutect2, varscan2
- TEP1 | c.1003G>C p.D335H | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99403459; called by muse, mutect2, varscan2
- THOC3 | c.602A>G p.N201S | Missense Mutation (SNP) | VAF 49/195 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as COSV99442296; called by muse, mutect2, varscan2
- TIMP2 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.041); catalogued as rs1358820636, COSV99431031; called by muse, mutect2
- TMEM214 | c.372G>C p.Q124H | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV99476581; called by muse, mutect2, varscan2
- TMEM51 | c.267G>T p.R89S | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as COSV101051582; called by muse, mutect2, varscan2
- TMEM71 | c.125G>C p.G42A | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.814); catalogued as COSV100785561; called by muse, mutect2, varscan2
- TP53 | c.425del p.P142Lfs*28 | Frame Shift Del (DEL) | VAF 25/72 reads (35%) | catalogued as COSV52675441, COSV52815950; called by mutect2, pindel, varscan2
- TPRG1L | c.539A>G p.N180S | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99573569; called by muse, mutect2, varscan2
- TRPM2 | c.4322A>T p.E1441V | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV100309447; called by muse, mutect2, varscan2
- TRPM3 | c.499G>A p.D167N (on ENST00000357533 / NM_001366142.2; = p.D12N on NM_020952.6) | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as COSV62473351; called by muse, mutect2, varscan2
- TTC8 | c.183G>C p.Q61H (on ENST00000338104 / NM_001288781.1; = p.Q71H on NM_144596.4) | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV100581736, COSV57626860; called by muse, mutect2, varscan2
- WDPCP | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV99707240; called by muse, mutect2, varscan2
- WDR44 | c.2476A>T p.R826W | Missense Mutation (SNP) | VAF 45/70 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99562039; called by muse, mutect2, varscan2
- WRAP73 | c.1050C>T p.D350= | Splice Region (SNP) | VAF 14/44 reads (32%) | catalogued as COSV99573570; called by muse, mutect2, varscan2
- ZBED9 | c.2585A>G p.K862R | Missense Mutation (SNP) | VAF 54/144 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.178); catalogued as COSV101509419; called by muse, mutect2, varscan2
- ZFP91 | c.404C>G p.S135C | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV100284782; called by muse, mutect2, varscan2
- ZFR2 | c.1876G>A p.D626N | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs763789976, COSV99508015; called by mutect2, varscan2
- ZNF18 | c.1627T>G p.L543V | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.051); catalogued as COSV100503200; called by muse, mutect2
- ZNF430 | c.1000A>G p.T334A | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV55108831; called by muse, mutect2, varscan2
- ZNF534 | c.578A>G p.H193R (on ENST00000332323 / NM_001143939.3; = p.H180R on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs755418172, COSV99990334; called by muse, mutect2, varscan2
- ZNF594 | c.536G>A p.G179E | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV101280595; called by muse, mutect2, varscan2
- ZNF75A | c.825T>A p.C275* | Nonsense Mutation (SNP) | VAF 39/155 reads (25%) | catalogued as COSV101556696; called by muse, mutect2, varscan2
- ZNF808 | c.164A>G p.E55G | Missense Mutation (SNP) | VAF 120/210 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100708264; called by muse, mutect2, varscan2
- ATG3 | c.543_544dup p.C182Ffs*47 | Frame Shift Ins (INS) | VAF 14/55 reads (25%) | called by mutect2, pindel, varscan2
- EEF2 | c.371_373dup p.G124dup | In Frame Ins (INS) | VAF 8/73 reads (11%) | called by mutect2, pindel, varscan2
- FGD6 | c.3331del p.L1111Cfs*19 | Frame Shift Del (DEL) | VAF 7/71 reads (10%) | called by mutect2, varscan2
- IGHV1-3 | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 9/137 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- IGKC | c.275A>G p.Q92R | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- MAST2 | c.895dup p.S299Kfs*12 | Frame Shift Ins (INS) | VAF 44/161 reads (27%) | called by mutect2, pindel, varscan2
- MRC1 | c.2111+2T>C p.X704_splice | Splice Site (SNP) | VAF 24/178 reads (13%) | called by muse, mutect2, varscan2
- MRC1 | c.4181T>C p.I1394T | Missense Mutation (SNP) | VAF 11/349 reads (3%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2
- OR56A1 | c.867del p.L290* | Frame Shift Del (DEL) | VAF 32/79 reads (41%) | called by mutect2, pindel, varscan2
- POLR2A | c.5381C>G p.S1794* | Nonsense Mutation (SNP) | VAF 305/609 reads (50%) | called by muse, mutect2, varscan2
- RYR3 | c.8140_8142del p.S2714del (on ENST00000389232; = p.S2715del on NM_001036.6) | In Frame Del (DEL) | VAF 11/33 reads (33%) | called by mutect2, pindel, varscan2
- TBC1D3F | c.234G>T p.W78C | Missense Mutation (SNP) | VAF 153/241 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- TBXAS1 | c.1226+6_1226+7del p.X409_splice | Splice Site (DEL) | VAF 30/98 reads (31%) | called by pindel, varscan2
- ZFYVE1 | c.2122_2127del p.R708_P709del | In Frame Del (DEL) | VAF 28/104 reads (27%) | called by mutect2, pindel, varscan2
- AAR2 | c.519C>T p.R173= | Silent (SNP) | VAF 96/253 reads (38%) | catalogued as rs779633484, COSV100299455; called by muse, mutect2, varscan2
- ACSM4 | c.981C>T p.L327= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs372999373; called by muse, mutect2, varscan2
- ADCK1 | c.1449T>C p.S483= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as COSV99452854; called by muse, mutect2, varscan2
- ALMS1 | c.12477A>G p.Q4159= | Silent (SNP) | VAF 33/97 reads (34%) | catalogued as COSV100044050; called by muse, mutect2, varscan2
- C9 | c.237C>T p.T79= | Silent (SNP) | VAF 17/133 reads (13%) | catalogued as rs754596142; called by muse, mutect2, varscan2
- CABIN1 | c.1638C>G p.L546= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs1446192974, COSV99574207; called by muse, mutect2, varscan2
- CCDC173 | c.738G>A p.Q246= | Silent (SNP) | VAF 18/116 reads (16%) | catalogued as COSV101376719; called by muse, mutect2
- CLSTN1 | c.1980C>T p.V660= (on ENST00000377298 / NM_001009566.3; = p.V650= on NM_014944.4) | Silent (SNP) | VAF 39/296 reads (13%) | catalogued as COSV100790809; called by muse, mutect2, varscan2
- CTNNA2 | c.324C>G p.S108= | Silent (SNP) | VAF 18/126 reads (14%) | catalogued as COSV100786538, COSV63560144; called by muse, mutect2, varscan2
- CUBN | c.9240C>T p.F3080= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV100913712, COSV64724255; called by muse, mutect2
- CUX1 | c.3801A>G p.P1267= | Silent (SNP) | VAF 45/110 reads (41%) | catalogued as COSV99473426; called by muse, mutect2, varscan2
- DEAF1 | c.696G>A p.E232= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as rs761590763, COSV100102424; called by muse, mutect2, varscan2
- EIF5 | c.411C>T p.L137= | Silent (SNP) | VAF 7/90 reads (8%) | catalogued as COSV99385056; called by muse, mutect2
- ERICH3 | c.4473A>G p.L1491= | Silent (SNP) | VAF 110/235 reads (47%) | catalogued as COSV100446063; called by muse, mutect2, varscan2
- FAM126B | c.1458A>T p.R486= | Silent (SNP) | VAF 133/191 reads (70%) | catalogued as COSV99628335; called by muse, mutect2, varscan2
- FAM166C | c.153C>T p.D51= | Silent (SNP) | VAF 43/122 reads (35%) | catalogued as COSV100297321; called by muse, mutect2, varscan2
- FGA | c.2130C>T p.G710= | Silent (SNP) | VAF 74/148 reads (50%) | catalogued as COSV100120829; called by muse, mutect2, varscan2
- GIMAP4 | c.463C>A p.R155= | Silent (SNP) | VAF 12/86 reads (14%) | called by muse, mutect2, varscan2
- GLIS1 | c.963G>A p.P321= | Silent (SNP) | VAF 70/149 reads (47%) | catalogued as rs148036745; called by muse, mutect2, varscan2
- GORAB | c.93G>C p.A31= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as COSV100883791, COSV63026212; called by muse, mutect2, varscan2
- HCN2 | c.651C>A p.T217= | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as COSV99242409; called by muse, mutect2, varscan2
- HELZ | c.1455G>A p.Q485= | Silent (SNP) | VAF 20/170 reads (12%) | catalogued as COSV100699117; called by muse, mutect2, varscan2
- HES7 | c.6C>T p.V2= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV100502975; called by muse, mutect2, varscan2
- IGLV1-51 | c.219G>A p.K73= | Silent (SNP) | VAF 132/311 reads (42%) | catalogued as rs762628074; called by muse, mutect2, varscan2
- IGLV3-16 | c.96C>T p.S32= | Silent (SNP) | VAF 61/160 reads (38%) | catalogued as rs747179267; called by muse, mutect2, varscan2
- ITGB7 | c.1713C>A p.G571= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as COSV99914310; called by muse, mutect2, varscan2
- KNTC1 | c.5559C>A p.L1853= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV100338906; called by muse, mutect2, varscan2
- MLH1 | c.1902G>C p.G634= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as COSV99212852; called by muse, mutect2, varscan2
- MLIP | c.312G>T p.T104= | Silent (SNP) | VAF 23/115 reads (20%) | catalogued as COSV51433839, COSV99230786; called by muse, mutect2, varscan2
- MSH5 | c.735C>T p.A245= | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as COSV100995000; called by muse, mutect2, varscan2
- P2RY10 | c.264C>A p.P88= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as COSV50680605, COSV99409459; called by muse, mutect2, varscan2
- PDCD2L | c.198G>T p.L66= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as COSV99875180; called by muse, mutect2, varscan2
- PNPLA7 | c.1656G>C p.L552= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV99481672; called by muse, mutect2, varscan2
- POLR1B | c.1500G>T p.V500= | Silent (SNP) | VAF 32/99 reads (32%) | catalogued as COSV54495402, COSV99638719; called by muse, mutect2, varscan2
- PRODH2 | c.984G>T p.V328= (on ENST00000301175; = p.V252= on NM_021232.2 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV99995564; called by muse, mutect2
- RABEP1 | c.270G>A p.A90= | Silent (SNP) | VAF 32/68 reads (47%) | catalogued as rs1478330552, COSV99337070; called by muse, mutect2, varscan2
- RFXANK | c.444C>T p.A148= | Silent (SNP) | VAF 19/309 reads (6%) | catalogued as rs772802002, COSV57394817; called by muse, mutect2
- RNF145 | c.1263T>A p.S421= (on ENST00000424310 / NM_001199383.2; = p.S449= on NM_144726.2) | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV99193927; called by muse, mutect2, varscan2
- RNF213 | c.1647G>C p.L549= | Silent (SNP) | VAF 10/93 reads (11%) | catalogued as COSV100174089; called by muse, mutect2, varscan2
- SBF1 | c.4068G>T p.G1356= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV100818095; called by muse, mutect2
- SCNN1A | c.510C>G p.L170= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV99965013; called by muse, mutect2, varscan2
- SEC24D | c.945A>G p.T315= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as COSV99756959; called by muse, mutect2, varscan2
- SEMA6C | c.681C>A p.V227= | Silent (SNP) | VAF 6/65 reads (9%) | catalogued as COSV100501648; called by muse, mutect2
- SLC12A3 | c.1161G>T p.L387= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as COSV99344894; called by muse, mutect2, varscan2
- SOX8 | c.543C>A p.A181= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV99559410; called by muse, mutect2, varscan2
- SPTBN4 | c.5568G>A p.R1856= | Silent (SNP) | VAF 14/104 reads (13%) | catalogued as COSV58961516; called by muse, mutect2, varscan2
- TLN1 | c.5040C>T p.L1680= | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as rs762759883, COSV100148347; called by muse, mutect2, varscan2
- TOM1 | c.615C>T p.S205= | Silent (SNP) | VAF 37/164 reads (23%) | catalogued as rs578123280, COSV101147170; called by muse, mutect2, varscan2
- ZNF140 | c.223C>T p.L75= | Silent (SNP) | VAF 10/44 reads (23%) | called by muse, mutect2, varscan2
- ATP11C | c.*25A>G | 3'UTR (SNP) | VAF 5/25 reads (20%) | catalogued as rs1186048958, COSV100558820; called by muse, mutect2
- MFRP | chr11:119346139 G>T | 5'Flank (SNP) | VAF 13/16 reads (81%) | catalogued as COSV100793560; called by muse, varscan2
- OBSCN | c.18662-2025C>A | Intron (SNP) | VAF 14/35 reads (40%) | catalogued as COSV52829304, COSV99485588; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-20226G>T | Intron (SNP) | VAF 14/34 reads (41%) | catalogued as rs747243561, COSV101045320; called by muse, varscan2
